Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5202, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5202-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA-BP-5202

Clinical Diagnosis & History:

Right renal mass. ✓

Specimens Submitted:

1: Kidney, right, partial nephrectomy (c) ✓

DIAGNOSIS:

1. Kidney, right, partial nephrectomy (c)

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 3.0 cm. ✓

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3a Tumor invades the adrenal gland or perinephric tissues but not beyond Gerota's fascia ✓

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled "Right renal tumor" and consists of a partial nephrectomy specimen, measuring 3.5 x 3.7 x 2.9 cm, with attached perinephric fat. The surgical margin is inked brown rough and has been inked black. The specimen is sectioned to reveal a well-circumscribed dark red tan tumor mass, which measures 3.0 x 2.5 x 2.4 cm, which is situated 0.2 cm from the nearest inked resected margin. The tumor is partially surrounded by a rim of pink brown grossly unremarkable renal parenchyma. Sections of the perinephric fat reveal focal hemorrhage and no abnormalities. Representative sections are submitted to TPS, for frozen section consultation, and for permanent section. The specimen has been photographed.

Summary of sections:

FSC - frozen section control

N - normal kidney

T - tumor with margin, capsule, and perinephric fat

Summary of Sections:

Part 1: Kidney, right, partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
1	n	1
2	t	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the Intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS; SP: Right renal tumor Renal cortical neoplasm. Stitched margin benign.

PERMANENT DIAGNOSIS:

Source: NCI Genomic Data Commons file 4163e365-7f9a-4516-be11-4109ee5affd1 (TCGA-BP-5202.01C3D30F-C78F-4162-8F5D-0D5643C0C01F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).